Gene-level copy-number profile of tumor specimen TCGA-CC-A3MB-01A from TCGA case TCGA-CC-A3MB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 36.3 years (13,255 days).
Specimen TCGA-CC-A3MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.5c92ffe9-e8b2-45f9-810f-c4252285ffd8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A3MB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2ef16d86-43cf-4834-b4e4-ce1b2c78be33

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 7; copy number 2: 18,590; copy number 3: 25,219; copy number 4: 11,723; copy number 5: 3,193; copy number 6: 337; copy number 7: 675; copy number 8: 10; copy number 10: 2; copy number 12: 42; copy number 57: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A3MB-01A-11D-A20V-01): tumor purity 0.59, ploidy 5.99, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:116,398,157–116,400,606, 1 gene: PAPPA-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 746 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:173,714,941–176,447,919, 52 genes, copy number 8–12: KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1, TNR, TNR-IT1, LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr8:108,871,128–109,121,565, 2 genes, copy number 10 (within-gene range 5–10): AC104248.1, TRHR.
- chr10:44,712–38,783,108, 675 genes, copy number 7 (broad region; genes not listed).
- chr11:69,294,151–69,926,813, 17 genes, copy number 57: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
